Gene-level copy-number profile of tumor specimen TCGA-DX-AB35-01A from TCGA case TCGA-DX-AB35, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Descending colon; Age at diagnosis: 65.8 years (24,026 days).
Specimen TCGA-DX-AB35-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.7603be2c-0856-4a97-a31c-9379708a0707.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB35-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ceefc04a-3b06-466a-8211-f0bf141e3dab

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 2,503; copy number 2: 7,718; copy number 3: 21,327; copy number 4: 23,675; copy number 5: 3,029; copy number 6: 870; copy number 7: 161; copy number 8: 280; copy number 9: 1; copy number 11: 17; copy number 12: 4; copy number 13: 2; copy number 14: 3; copy number 15: 4; copy number 16: 50; copy number 17: 17; copy number 19: 23; copy number 21: 11; copy number 23: 13; copy number 24: 68; copy number 28: 4; copy number 30: 16; copy number 34: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB35-01A-21D-A416-01): tumor purity 0.85, ploidy 3.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:114,234,887–114,337,626, 7 genes (within-gene range 0–2): CDC16, MIR4502, AL160396.2, UPF3A, CLCP2, CHAMP1, LINC01054.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 244 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:224,703,764–225,654,018, 4 genes, copy number 12 (within-gene range 8–12): CCDC195, DOCK10, MIR4439, NYAP2.
- chr2:225,992,981–226,185,371, 2 genes, copy number 13: AC068138.1, AC062015.1.
- chr11:104,942,866–105,035,250, 4 genes, copy number 15 (within-gene range 1–15): CASP4, AP001153.1, CASP5, CASP1.
- chr12:59,450,673–59,586,943, 3 genes, copy number 21: RNU6-871P, LINC02448, RNU4-20P.
- chr12:60,341,824–61,702,771, 6 genes, copy number 14–28: Y_RNA, AC090022.1, AC090022.2, AC090017.1, DUX4L52, AC090629.1.
- chr12:61,775,923–61,880,772, 2 genes, copy number 19–28: RPL21P104, KRT8P19.
- chr12:62,935,701–63,360,037, 10 genes, copy number 16: Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1.
- chr12:63,623,788–63,795,718, 1 gene, copy number 16 (within-gene range 4–16): AC084357.2.
- chr12:63,682,523–64,397,065, 18 genes, copy number 16 (within-gene range 6–16): AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P.
- chr12:64,266,413–64,266,766, 1 gene, copy number 16: OOEPP2.
- chr12:65,050,626–65,491,430, 6 genes, copy number 16–19 (within-gene range 3–19): WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3.
- chr12:65,418,731–66,170,072, 19 genes, copy number 16 (within-gene range 3–16): KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4.
- chr12:68,746,125–71,586,310, 52 genes, copy number 11–24 (within-gene range 3–24): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1.
- chr12:71,938,845–72,670,758, 6 genes, copy number 17 (within-gene range 8–17): TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2.
- chr12:73,648,666–74,402,600, 11 genes, copy number 34 (within-gene range 3–34): AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3.
- chr12:74,656,561–76,139,671, 33 genes, copy number 19–30: AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6, RN7SL734P, AC011611.2, AC011611.1, PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5, AC233290.2, AC233290.1, RNU6-1271P.
- chr12:76,757,191–79,690,964, 27 genes, copy number 9–24 (within-gene range 8–24): AC093014.1, ZDHHC17, CSRP2, AC124784.1, AC025161.1, E2F7, AC079030.1, LINC02464, NAV3, AC073591.1, AC138331.1, AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2, SYT1, AC090709.1, AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR.
- chr12:79,934,901–80,770,717, 13 genes, copy number 23: PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1, RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490.
- chr12:81,868,368–82,479,239, 5 genes, copy number 21 (within-gene range 3–21): AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25.
- chr12:83,021,890–83,172,740, 3 genes, copy number 17: RNU6-977P, RPL6P25, AC090680.1.
- chr12:88,492,793–88,600,725, 3 genes, copy number 21 (within-gene range 3–21): KITLG, AC024941.2, RNU1-117P.
- chr12:91,984,976–92,363,832, 8 genes, copy number 11 (within-gene range 3–11): LINC01619, AC123512.1, AC025164.2, BTG1, AC025164.1, RPL21P106, Y_RNA, LINC02391.
- chr12:125,065,434–125,662,377, 7 genes, copy number 11 (within-gene range 3–11): AACS, AC122688.3, AC122688.2, AC122688.5, AC122688.4, TMEM132B, AC093028.1.

Autosomal genes at a single copy (total copy number 1): 1,414. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
